Gene-level copy-number profile of tumor specimen TCGA-BR-4366-01A from TCGA case TCGA-BR-4366, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Gastric antrum; Tumor grade: G2; Age at diagnosis: 87.7 years (32,024 days).
Specimen TCGA-BR-4366-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.40f33f55-d207-44f9-b4d1-5ba6106794e4.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BR-4366-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7e0d2c5a-e078-429f-9afd-46f441d551ec

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 30; copy number 1: 443; copy number 2: 12,916; copy number 3: 5,219; copy number 4: 29,099; copy number 5: 3,035; copy number 6: 5,004; copy number 7: 660; copy number 8: 1,765; copy number 9: 795; copy number 10: 257; copy number 11: 198; copy number 12: 114; copy number 13: 29; copy number 14: 133; copy number 16: 3; copy number 19: 1; copy number 21: 18; copy number 24: 54; copy number 27: 34; copy number 36: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BR-4366-01A-01D-1155-01): tumor purity 0.8, ploidy 2.07, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 15 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:186,590,056–186,765,959, 3 genes (within-gene range 0–2): ITGAV, AC017101.1, FAM171B.
- chr16:71,623,708–71,835,932, 12 genes: AC009097.2, MARVELD3, PHLPP2, AC009097.1, RNU6-208P, SNORA70D, AC009097.4, AC009097.3, AP1G1, SNORD71, AC010653.3, AC010653.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,640 genes in 21 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:168,576,605–169,132,722, 13 genes, copy number 12: XCL1, DPT, AL135926.1, AL031275.1, LINC00626, SUMO1P2, AL135926.2, LINC00970, RPL29P7, AL031726.2, RNA5SP66, AL031726.1, ATP1B1.
- chr1:178,411,616–180,566,523, 57 genes, copy number 12 (within-gene range 8–12): AL365357.1, CLEC20A, Metazoa_SRP, AL513013.1, TEX35, C1orf220, RNA5SP69, AL137796.1, MIR4424, AL449106.1, RALGPS2, PTPN2P1, SNORA63, ANGPTL1, FAM20B, AL139132.1, TOR3A, ABL2, AL512326.5, SETP10, AL512326.2, AL512326.1, EIF4A1P11, AL512326.3, COX5BP8, AL512326.4, SOAT1, AXDND1, MEF2AP1, HNRNPA1P54, AL160286.3, NPHS2, RNU5F-2P, AL160286.1, AL160286.2, TDRD5, AL359853.2, FAM163A, AL359853.1, LINC02818, TOR1AIP2, AL353708.3, TOR1AIP1, RN7SL230P, AL353708.2, AL353708.1, CEP350, RPSAP16, AL590632.1, AL390718.1, QSOX1, LHX4, ACBD6, VDAC1P4, MIR3121, OVAAL, Y_RNA.
- chr3:80,163,327–80,789,388, 6 genes, copy number 10 (within-gene range 5–10): OSBPL9P1, HNRNPA3P8, AC108740.1, AC108690.1, AC068756.1, LINC02050.
- chr4:136,795,919–140,154,184, 55 genes, copy number 10–13 (within-gene range 3–13): LINC02511, LINC02510, SERF1AP1, STMN1P2, RPS23P2, PCDH18, LINC02172, AC116563.2, AC116563.1, AC131956.2, AC131956.3, AC131956.1, AC097511.1, LINC00616, SLC7A11-AS1, SLC7A11, AC093903.1, LINC00498, LINC00499, LINC00500, AC105416.1, AC098859.1, AC098859.2, AC093766.1, AC109927.1, AC109927.2, NOCT, ELF2, RNU6-531P, RN7SL382P, PPP1R14BP3, Metazoa_SRP, RN7SL311P, Y_RNA, RNU6-506P, RNU6-1074P, MGARP, NDUFC1, NAA15, RNU6-1214P, AC097376.3, AC097376.2, AC097376.1, RAB33B, SETD7, FTH1P24, AC112236.2, AC112236.3, AC112236.1, MGST2, RN7SKP237, H3P16, MAML3, AC108053.1, RN7SKP253.
- chr4:147,344,629–152,178,573, 72 genes, copy number 10 (within-gene range 3–10) (broad region; genes not listed).
- chr5:2,184,710–45,895,970, 633 genes, copy number 9 (broad region; genes not listed).
- chr6:163,115,691–164,348,644, 18 genes, copy number 9: AL137182.1, PACRG-AS3, PACRG-AS1, AL031121.2, AL031121.3, AL031121.1, CAHM, QKI, AL445307.1, AL078602.1, AL137005.1, RN7SL366P, AL136225.1, Z97205.2, Z97205.1, Z97205.3, AL139190.1, AL358972.1.
- chr6:166,157,656–170,738,536, 119 genes, copy number 9 (within-gene range 7–9) (broad region; genes not listed).
- chr11:70,467,856–71,252,577, 1 gene, copy number 10 (within-gene range 7–10): SHANK2.
- chr11:70,705,167–74,949,200, 158 genes, copy number 9–10 (within-gene range 8–10) (broad region; genes not listed).
- chr11:76,591,023–76,804,555, 12 genes, copy number 10: AP001189.2, LINC02757, AP001189.5, AP001189.3, AP001189.1, LRRC32, AP001189.4, GUCY2EP, AP003119.1, TSKU, AP003119.2, AP003119.3.
- chr11:84,887,207–88,428,176, 74 genes, copy number 12–36 (broad region; genes not listed).
- chr13:33,103,137–33,802,853, 11 genes, copy number 10 (within-gene range 6–10): STARD13, STARD13-IT1, STARD13-AS, AL627232.1, LINC02344, AL138999.2, AL138999.1, AL139383.1, AL161719.1, AL139081.1, AL139081.2.
- chr13:33,829,539–33,829,649, 1 gene, copy number 10: RNU5A-4P.
- chr13:39,209,116–48,711,226, 185 genes, copy number 11 (within-gene range 8–11) (broad region; genes not listed).
- chr13:73,100,575–73,113,018, 2 genes, copy number 10: FABP5P1, RNU6-66P.
- chr18:36,777,647–39,034,110, 16 genes, copy number 14 (within-gene range 8–14): TPGS2, KIAA1328, AC016493.1, AC015961.1, CELF4, AC015961.2, AC090386.1, AC090386.2, AC129908.1, AC009899.1, MIR4318, RPL12P40, AC108452.1, AC100781.1, RN7SKP182, RNU6-706P.
- chr18:39,314,240–39,335,672, 2 genes, copy number 14: AC011139.1, RPL7AP66.
- chr19:27,638,483–30,872,507, 67 genes, copy number 11–21 (broad region; genes not listed).
- chr20:15,892,355–15,985,876, 1 gene, copy number 19: AL079338.1.
- chr20:47,656,348–54,651,169, 137 genes, copy number 12–27 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 443. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
